Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7304, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7304-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

Surgical Pathology Report

[REDACTED]

[REDACTED]

Physician(s): [REDACTED]
Phy Location: [REDACTED]

=====

CLINICAL HISTORY

[REDACTED] man with two separate seizure episodes has infiltrative lesion involving frontal lobes, corpus callosum, and mesial left temporal and parietal lobes, with focal area of enhancement close to the genu of the corpus callosum.

OPERATIVE DIAGNOSES
Not Given

Operation/Specimen: A: Left frontal brain tumor
B: Left frontal brain tumor

PATHOLOGICAL DIAGNOSIS:
A and B. Brain, left frontal, biopsy and excision:
1. Oligoastrocytoma, diffusely infiltrative, with anaplastic features.
2. MIB-1 proliferation index: 18%.

See Microscopy Description and Comment.

COMMENT

Part A is cerebral tissue infiltrated by large, very atypical naked nuclei, with occasional mitoses.
Part B is portions of cerebrum moderately to heavily infiltrated by a glial neoplastic proliferation with prominent nuclear atypia and sparse mitoses throughout the tumor. There is no microvascular cellular proliferation or appreciable necrosis. The MIB-1 proliferation index is high at about 18% in the more active areas.
The tumor has a predominant astrocytic phenotype, but it does appear to have

[page 2 of 4]
an oligodendroglial component. The nuclear atypia and high proliferation index are atypical features ("intermediate grade"). In the tissues examined the neoplasm does not have the brisk mitotic activity and necrosis observed in WHO grade III tumors. Correlation with imaging and operative findings may help in better grading the neoplasm.

=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: Date Reported:

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing was done on block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

=====

[page 3 of 4]
INTRA-OPERATIVE CONSULTATION

A. Left frontal brain tumor, touch prep and smears: Neoplasm, diffusely infiltrating, cytologically anaplastic (C/W high grade glioma). Frozen section performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED] Senior Staff Pathologist

GROSS DESCRIPTION

A.

Received fresh, four fragments, 1.4 cm. in aggregate. Semi firm, tannish-white, focally purplish. In total, A1 and A2.

B.

SPECIMEN: Left frontal brain tumor.

FIXATIVE: None.

GENERAL: Two, 0.8 x 0.7 x 0.5 cm and 2.7 x 1.5 x 1.2 cm red to gray-tan

fragments of brain tissue with a combined weight of 2.01 gm. The largest fragment is sectioned.

SECTIONS: B1 small fragment entirely submitted, B2, B3 larger fragment entirely submitted.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates heavy gliofibrillogenesis by the neoplastic cells. About one fourth of the neoplastic cells strongly over

express the p53 protein. With the MIB-1 there is a proliferation index of about 18% in the more active areas.

The immuno profile is compatible with an actively proliferating glioma.

ICD-9(s):

239.6 239.6

Histo Data

Part A: Left frontal brain tumor

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
mGFAP-DA x 1		1		
H/E x 1		1		
MIB1-DA x 1		1		
P53DO7 x 1		1		

[page 4 of 4]
TPS H/E x 1	1	[REDACTED]
H/E x 1	2	[REDACTED]
H/E x 1	3	[REDACTED]

Part B: Left frontal brain tumor

Taken: [REDACTED]	Received: [REDACTED]
Stain/cnt	Block Ordered Comment
mGFAP-DA x 1	1 [REDACTED]
H/E x 1	1 [REDACTED]
MIB1-DA x 1	1 [REDACTED]
mGFAP-DA x 1	2 [REDACTED]
H/E x 1	2 [REDACTED]
MGMT x 1	2 [REDACTED]
MIB1-DA x 1	2 [REDACTED]
P53DO7 x 1	2 [REDACTED]
H/E x 1	3 [REDACTED]

*** End of Report ***

Source: NCI Genomic Data Commons file b15f992a-1b3f-4921-ac1d-bb8981d5431c (TCGA-DU-7304.FC0E1343-BD97-4F43-AA22-1AEC3FEB9D83.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).